Somatic mutation profile of tumor specimen 0DOQGJ from CCDI case PBCCGJ, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Papillary carcinoma, NOS; Tissue or organ of origin: Thyroid gland; Age at diagnosis: 16.2 years (5,927 days).
Specimen 0DOQGJ: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7ead2439-b151-4b7f-a657-193af1ed7464.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DOQGN (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af6d64db-0dd2-47d8-a934-5376b2728f41

The open-access MAF lists 7 somatic variants for this specimen: 6 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Nonsense Mutation 2, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 300/758 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- GRK2 | c.1360C>T p.R454C | Missense Mutation (SNP) | VAF 182/514 reads (35%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as rs1208435182; called by muse, mutect2, varscan2
- SHISA9 | c.1138C>T p.R380W | Missense Mutation (SNP) | VAF 35/678 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV69631753; called by muse, mutect2
- SLC66A2 | c.461C>T p.T154M | Missense Mutation (SNP) | VAF 32/586 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.639); catalogued as rs770487880; called by muse, mutect2
- TMCO4 | c.1447C>T p.Q483* | Nonsense Mutation (SNP) | VAF 273/636 reads (43%) | catalogued as rs748633593; called by muse, mutect2, varscan2
- SHB | c.1021G>T p.E341* | Nonsense Mutation (SNP) | VAF 248/603 reads (41%) | called by muse, mutect2, varscan2
- ANP32A | c.-71G>A | 5'UTR (SNP) | VAF 12/122 reads (10%) | called by muse, mutect2, varscan2
